Surgical pathology report (de-identified scan), TCGA case TCGA-H2-A3RH, project TCGA-THCA (Thyroid Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-H2-A3RH-01A (Primary Tumor).

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Thyroid, total thyroidectomy: Papillary carcinoma, follicular variant of the left lobe, organ confined and completely resected. Single ipsilateral focus of papillary microcarcinoma also present. Right lobe of thyroid with multinodular goiter.

B. Central cervical nodes, dissection: 3 lymph nodes all negative for metastatic disease, 0/3.

Microscopic Description:

A, B. The right lobe of this thyroid contains several benign nodules consistent with multinodular goiter. The left lobe contains a follicular variant of papillary carcinoma, measuring 1.7 cm in maximum dimension. It discloses nuclear clearing, nuclear grooves and psammoma bodies. It is mostly but not entirely encapsulated. Nearby, there is a 0.3 mm satellite focus of papillary microcarcinoma. The tumor is organ confined and completely resected.

Histologic type: Papillary carcinoma, follicular variant

Primary tumor (pT): pT1b

Margins of resection: Negative

Vascular invasion: Negative

Regional lymph nodes (pN): As per part B., all 3 lymph nodes are negative for metastatic disease, 0/3, pN0

Distant metastasis (pM): pM0

Other findings: Multinodular goiter within right lobe. Within the left lobe a 2nd focus of papillary microcarcinoma is noted.

Specimen

A. Total thyroid silk right upper pole

B. Central cervical node dissection

Clinical Information

Papillary cancer of thyroid

Gross Description

A. Received fresh for frozen section labeled "total thyroid" is an 11.7 g, roughly symmetrical total thyroidectomy with right and left lobes averaging 3.9 x 3.1 x 1.2 cm. The capsule is delicate tan-pink without identifiable lymphoid or parathyroid tissues posteriorly. The right lobe is inked blue and the left lobe is inked black. A well-circumscribed, 1.7 x 1.3 x 1.0 cm rubbery pale tan nodule is present within the superior pole of the left lobe. The nodule extends to within 0.1 cm of the capsular surface. A representative section is submitted for Tissue Procurement. The remaining parenchyma throughout the specimen is beefy red-brown with a few additional pale tan nodules measuring up to 0.8 cm.

Summary: 1 through 4 - right lobe, superior to inferior; 5 through 9 - left lobe, superior to inferior

B. Received fresh labeled "central cervical node dissection" is a 1.4 x 1.2 x 0.3 cm aggregate of soft, lobulated tan gold adipose tissue. 2 slightly rubbery tan-pink tissues in keeping with lymph nodes measuring up to 0.3 cm are recovered.

Summary: 1 - 2 lymph nodes; 2 - residual adipose tissue

1CD-0-3
Carcinoma, papillary,
follicular variant
8340/3
Site: thyroid, NOS
C73.9
3.9 1.2 1.2

Source: NCI Genomic Data Commons file 8f485bd9-2344-4dd7-9f4b-00484f514796 (TCGA-H2-A3RH.4F197857-EB50-4345-BAD0-05D27B02D06D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).